Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8QA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8QA-01A (Primary Tumor).

Collect date.
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

I-) Periaortic lymph nodes.
- Absence of neoplasia (0/7).

II-) Right pelvic lymph nodes.
- Absence of neoplasia (0/13).

III) Left pelvic lymph nodes.
- Absence of neoplasia (0/6).

IV-) Uterus and adnexae.

- Uterus.
. Invasive poorly differentiated squamous cell carcinoma measuring 1.6 cm of extension and 0.8 cm depth.
. The tumor infiltrates until the middle third of the cervical stroma.
. Presence of lymphatic invasion.
. Absence of perineural invasion.
. High-grade intraepithelial squamous neoplasia, involving the ectocervix and the vaginal cuff.
. Atrophic endometrium.
. Isthmus not involved by neoplasia.
. Parametrium not involved by neoplasia.
. Vaginal margin focally involved by high-grade intraepithelial neoplasia.

- Uterine tubes:
. No particularities.

- Right ovary:
. Serous cyst adenoma.
. Cysts of inclusion in the superficial epithelium.

- Left ovary:
. Atrophy.

V-) Surgical vaginal margin expansion
- Absence of neoplasia.

ICD O-3

Carcinoma, squamous cell NOS
8070/3

Site ^{Cervix} NOS C53.9

^{path} Uterus NOS C55.9

W 08/14

Source: NCI Genomic Data Commons file 4f3b3f01-252d-4b84-bbe1-5e030a218def (TCGA-VS-A8QA.EECF9BD1-22C3-41FC-8357-8ABB54515DE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).